Somatic mutation profile of tumor specimen C3N-03052-01 (aliquot CPT0236000012) from CPTAC case C3N-03052, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 63.0 years (23,009 days).
Specimen C3N-03052-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37897de1-ff8b-4e0a-a818-4a12e62ab847.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03052-31 (Blood Derived Normal), aliquot CPT0236050002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed369f78-850d-4a24-a63c-fd5acb8f7f99

The open-access MAF lists 157 somatic variants for this specimen: 109 protein-altering or splice-affecting, 33 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 33, Nonsense Mutation 8, Frame Shift Del 8, Splice Site 7, RNA 4, Intron 4, 3'UTR 4, Nonstop Mutation 1, 3'Flank 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 478/912 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ADAMTS17 | c.2087G>A p.G696D | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs369034695; called by muse, mutect2
- C1QL2 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.034); catalogued as rs764589165; called by muse, mutect2, varscan2
- CD48 | c.731G>T p.*244Lext*5 | Nonstop Mutation (SNP) | VAF 11/318 reads (3%) | catalogued as COSV100924198, COSV63565883; called by muse, mutect2
- CEP72 | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 16/474 reads (3%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs140817509; called by muse, mutect2
- COL11A1 | c.29C>G p.T10R | Missense Mutation (SNP) | VAF 17/489 reads (3%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.983); catalogued as COSV62176577; called by muse, mutect2
- EGFR | c.2270A>T p.K757M | Missense Mutation (SNP) | VAF 318/620 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs397517102, COSV51841095, COSV51850613; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRK1 | c.1508_1509del p.T503Rfs*120 | Frame Shift Del (DEL) | VAF 64/215 reads (30%) | catalogued as rs1179741805; called by pindel, varscan2
- IFFO2 | c.1199A>T p.N400I | Missense Mutation (SNP) | VAF 100/272 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.894); catalogued as COSV100841965; called by muse, mutect2, varscan2
- INTS2 | c.1220A>C p.E407A | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs199843960; called by muse, mutect2, varscan2
- KALRN | c.524C>G p.S175C | Missense Mutation (SNP) | VAF 49/338 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.794); catalogued as COSV53784611; called by mutect2, varscan2
- KIAA0100 | c.1418G>A p.R473H | Missense Mutation (SNP) | VAF 48/346 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs765801518, COSV66496365; called by muse, mutect2, varscan2
- KLHDC7B | c.1405G>T p.V469L (on ENST00000395676; = p.V1110L on NM_138433.5) | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as rs1160340948; called by muse, mutect2
- KMT2D | c.6533G>T p.G2178V | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as COSV56497411; called by muse, mutect2
- LPA | c.4510C>T p.H1504Y | Missense Mutation (SNP) | VAF 103/286 reads (36%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1235648070; called by muse, mutect2, varscan2
- LRRFIP1 | c.721C>A p.L241M (on ENST00000392000 / NM_001137552.2; = p.L217M on NM_004735.4) | Missense Mutation (SNP) | VAF 78/289 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs149852141; called by muse, mutect2, varscan2
- MCPH1 | c.826_829del p.S276Hfs*16 | Frame Shift Del (DEL) | VAF 45/135 reads (33%) | catalogued as rs1563216932; called by pindel, varscan2
- MXRA5 | c.3235C>T p.H1079Y | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs748884116; called by muse, mutect2, varscan2
- NAA35 | c.532A>G p.M178V | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.042); catalogued as rs201748422; called by muse, mutect2, varscan2
- NBPF11 | c.1558T>C p.W520R | Missense Mutation (SNP) | VAF 55/591 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.062); catalogued as rs1439627823; called by muse, mutect2, varscan2
- NCAM2 | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 8/179 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV53066927, COSV53094159; called by muse, mutect2
- NMUR2 | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 14/170 reads (8%) | catalogued as COSV54922895; called by muse, mutect2
- PHIP | c.4825C>G p.Q1609E | Missense Mutation (SNP) | VAF 7/203 reads (3%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.046); catalogued as rs1331670757; called by muse, mutect2
- PIK3CA | c.2230T>A p.F744I | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV55982794, COSV56008181; called by muse, mutect2, varscan2
- PTPRN | c.2123G>A p.R708H | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs370564509; called by muse, mutect2
- RAD21L1 | c.1163T>C p.V388A | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1477063094; called by muse, mutect2, varscan2
- RB1 | c.2107-2A>T p.X703_splice | Splice Site (SNP) | VAF 53/107 reads (50%) | catalogued as CS890135, COSV57316167; called by muse, mutect2, varscan2
- RB1 | c.2107-1G>T p.X703_splice | Splice Site (SNP) | VAF 55/110 reads (50%) | catalogued as CS125752, COSV57297199, COSV57304025; called by muse, mutect2, varscan2
- RFPL3 | c.839G>A p.R280H (on ENST00000249007 / NM_001098535.1; = p.R251H on NM_006604.2) | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.576); catalogued as rs140074264, COSV50747916; called by muse, mutect2, varscan2
- RIPOR3 | c.133G>C p.V45L | Missense Mutation (SNP) | VAF 63/176 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.058); catalogued as COSV50400143; called by muse, mutect2, varscan2
- RSRC2 | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 44/222 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.947); catalogued as rs1309774258; called by muse, mutect2, varscan2
- SCAF1 | c.1468C>T p.R490W | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as COSV62183807; called by muse, mutect2, varscan2
- SCAF4 | c.960-1G>A p.X320_splice | Splice Site (SNP) | VAF 20/124 reads (16%) | catalogued as COSV54590250; called by muse, mutect2, varscan2
- SEPTIN3 | c.100A>G p.I34V | Missense Mutation (SNP) | VAF 149/421 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1314356336; called by muse, mutect2, varscan2
- TCHH | c.5056C>T p.R1686C | Missense Mutation (SNP) | VAF 76/690 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as COSV64274827; called by muse, mutect2, varscan2
- TNRC6B | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 34/294 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.98); catalogued as rs759716158; called by muse, mutect2, varscan2
- TRAFD1 | c.644-1G>T p.X215_splice | Splice Site (SNP) | VAF 24/161 reads (15%) | catalogued as rs1451932948; called by muse, mutect2, varscan2
- WDPCP | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.406); catalogued as COSV55434622; called by muse, mutect2, varscan2
- ZAN | c.2173A>G p.T725A | Missense Mutation (SNP) | VAF 49/375 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.259); catalogued as rs758854257; called by muse, mutect2, varscan2
- ZBTB11 | c.3035C>G p.S1012C | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV57247711; called by muse, mutect2
- ADGRB1 | c.4090A>C p.K1364Q | Missense Mutation (SNP) | VAF 22/496 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.044); called by muse, mutect2
- ANAPC7 | c.1264A>T p.S422C | Missense Mutation (SNP) | VAF 9/259 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- ANKEF1 | c.1339C>T p.Q447* | Nonsense Mutation (SNP) | VAF 60/198 reads (30%) | called by muse, mutect2, varscan2
- C12orf65 | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 96/610 reads (16%) | called by muse, mutect2, varscan2
- C16orf89 | c.1202G>A p.G401E | Missense Mutation (SNP) | VAF 64/368 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- C16orf96 | c.1822G>A p.A608T | Missense Mutation (SNP) | VAF 12/372 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- CARMIL3 | c.3619C>T p.P1207S | Missense Mutation (SNP) | VAF 93/475 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCL16 | c.149T>C p.L50P | Missense Mutation (SNP) | VAF 73/349 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DBR1 | c.164C>G p.P55R | Missense Mutation (SNP) | VAF 46/408 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCC | c.3757G>A p.V1253M | Missense Mutation (SNP) | VAF 17/327 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); called by muse, mutect2
- DCLRE1C | c.787G>C p.E263Q (on ENST00000378278 / NM_001350965.2; = p.E148Q on NM_022487.4) | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- EMILIN2 | c.2942del p.H981Lfs*34 | Frame Shift Del (DEL) | VAF 164/569 reads (29%) | called by mutect2, pindel, varscan2
- ENPP3 | c.2197C>T p.L733F | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ERN1 | c.1327G>C p.D443H | Missense Mutation (SNP) | VAF 62/622 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- FAM71B | c.82C>A p.L28M | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBXO40 | c.1507C>G p.L503V | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.415); called by muse, mutect2
- GREB1 | c.5755G>T p.E1919* | Nonsense Mutation (SNP) | VAF 46/322 reads (14%) | called by muse, mutect2, varscan2
- HDAC7 | c.2779G>T p.A927S (on ENST00000427332; = p.A966S on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/250 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- HLA-F | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 33/274 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HNF4A | c.971A>G p.N324S | Missense Mutation (SNP) | VAF 26/234 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HNRNPH1 | c.707A>G p.Y236C | Missense Mutation (SNP) | VAF 9/185 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.037); called by muse, mutect2
- IFT57 | c.1018A>T p.T340S | Missense Mutation (SNP) | VAF 38/267 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- IL17RA | c.369A>C p.E123D | Missense Mutation (SNP) | VAF 115/605 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ITPR3 | c.6751A>G p.I2251V | Missense Mutation (SNP) | VAF 226/392 reads (58%) | SIFT tolerated (0.33); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- JKAMP | c.499C>G p.L167V (on ENST00000554271 / NM_001284201.1; = p.L153V on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- KCNC3 | c.816G>T p.W272C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- KIAA0825 | c.2577C>G p.C859W | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KMT2C | c.7386G>C p.Q2462H | Missense Mutation (SNP) | VAF 94/492 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- LAMA1 | c.2377_2380dup p.P794Lfs*18 | Frame Shift Ins (INS) | VAF 168/541 reads (31%) | called by mutect2, varscan2
- LCP2 | c.263T>A p.V88D | Missense Mutation (SNP) | VAF 33/317 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- LRRC4C | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRN1 | c.1889C>T p.T630I | Missense Mutation (SNP) | VAF 63/223 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MCM2 | c.2471T>A p.F824Y | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT tolerated (0.91); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MFSD2B | c.86G>C p.R29P | Missense Mutation (SNP) | VAF 39/190 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- MPPED1 | c.762G>A p.W254* | Nonsense Mutation (SNP) | VAF 42/287 reads (15%) | called by muse, mutect2, varscan2
- MTR | c.1321A>G p.I441V | Missense Mutation (SNP) | VAF 36/464 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.172); called by muse, mutect2
- MYADML2 | c.665del p.G222Afs*26 | Frame Shift Del (DEL) | VAF 144/747 reads (19%) | called by mutect2, pindel, varscan2
- NAALAD2 | c.452A>G p.Y151C | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- NFATC2IP | c.574T>G p.F192V | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.026); called by muse, mutect2
- PDSS1 | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 26/625 reads (4%) | called by muse, mutect2
- PPP4R1 | c.2278G>C p.A760P (on ENST00000400556 / NM_001042388.3; = p.A743P on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/249 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- PRDM2 | c.1369A>T p.I457F | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- PRELID1 | c.471G>T p.K157N | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); called by muse, mutect2
- PRUNE2 | c.5611C>G p.P1871A | Missense Mutation (SNP) | VAF 133/321 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PTPN20 | c.8C>A p.S3* | Nonsense Mutation (SNP) | VAF 51/437 reads (12%) | called by muse, mutect2, varscan2
- RAPGEF3 | c.1901A>G p.N634S (on ENST00000389212; = p.N592S on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/284 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF146 | c.574_578del p.L192Kfs*6 (on ENST00000368314 / NM_001242850.2; = p.L191Kfs*6 on NM_030963.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 68/192 reads (35%) | called by mutect2, pindel, varscan2
- RSC1A1 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.046); called by muse, mutect2
- RUNX1T1 | c.1414G>C p.E472Q (on ENST00000265814 / NM_001198628.1; = p.E445Q on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/287 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SCEL | c.978-3_1005del p.X326_splice (on ENST00000349847 / NM_144777.3; = p.X306_splice on NM_003843.4) | Splice Site (DEL) | VAF 25/60 reads (42%) | called by mutect2, pindel
- SIPA1 | c.2228C>A p.A743D | Missense Mutation (SNP) | VAF 148/346 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC7A13 | c.480G>C p.Q160H | Missense Mutation (SNP) | VAF 61/398 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SNRNP35 | c.239T>G p.L80R | Missense Mutation (SNP) | VAF 82/220 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- STK17B | c.84_87delinsAA p.F28Lfs*9 | Frame Shift Del (DEL) | VAF 14/99 reads (14%) | called by pindel, varscan2*
- TBR1 | c.1233del p.N412Tfs*26 | Frame Shift Del (DEL) | VAF 42/104 reads (40%) | called by mutect2, pindel
- TET3 | c.1322C>T p.T441I | Missense Mutation (SNP) | VAF 16/478 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.343); called by muse, mutect2
- TEX14 | c.514C>G p.L172V | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- TMPO | c.721_730del p.G241Rfs*3 | Frame Shift Del (DEL) | VAF 42/390 reads (11%) | called by mutect2, pindel
- TMX1 | c.804A>T p.Q268H | Missense Mutation (SNP) | VAF 176/260 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TP53 | c.547_559+6del p.X183_splice | Splice Site (DEL) | VAF 102/266 reads (38%) | called by mutect2, pindel, varscan2
- TRIM52 | c.662G>C p.S221T | Missense Mutation (SNP) | VAF 118/1014 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TTC22 | c.727C>G p.P243A | Missense Mutation (SNP) | VAF 136/416 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- USH2A | c.925C>A p.P309T | Missense Mutation (SNP) | VAF 93/122 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP6 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 14/456 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.874); called by muse, mutect2
- UTP11 | c.568-2A>T p.X190_splice | Splice Site (SNP) | VAF 51/157 reads (32%) | called by muse, mutect2, varscan2
- ZBTB16 | c.1665C>A p.F555L | Missense Mutation (SNP) | VAF 17/428 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- ZNF160 | c.2326C>A p.L776I | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- ZNF300 | c.495T>A p.N165K | Missense Mutation (SNP) | VAF 71/348 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF749 | c.1279C>T p.Q427* | Nonsense Mutation (SNP) | VAF 10/229 reads (4%) | called by muse, mutect2
- ANKEF1 | c.1338G>T p.R446= | Silent (SNP) | VAF 60/201 reads (30%) | catalogued as rs758756107, COSV65692173; called by muse, mutect2, varscan2
- ASPDH | c.30C>T p.G10= | Silent (SNP) | VAF 63/240 reads (26%) | catalogued as rs147876313; called by muse, mutect2, varscan2
- C1QBP | c.732C>T p.A244= | Silent (SNP) | VAF 71/131 reads (54%) | catalogued as rs771785492, COSV99852189; called by muse, mutect2, varscan2
- C3AR1 | c.1059A>T p.I353= | Silent (SNP) | VAF 150/252 reads (60%) | called by muse, mutect2, varscan2
- CACNA1I | c.6333C>T p.R2111= | Silent (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- CACNG2 | c.966C>T p.P322= | Silent (SNP) | VAF 24/129 reads (19%) | catalogued as rs1296749972; called by muse, mutect2, varscan2
- CCAR1 | c.1647C>G p.R549= | Silent (SNP) | VAF 33/223 reads (15%) | called by muse, mutect2, varscan2
- CHRD | c.2085T>C p.G695= | Silent (SNP) | VAF 14/329 reads (4%) | called by muse, mutect2
- CRYGC | c.109C>A p.R37= | Silent (SNP) | VAF 14/419 reads (3%) | catalogued as rs1040762144; called by muse, mutect2
- CYP2U1 | c.297G>C p.S99= | Silent (SNP) | VAF 182/458 reads (40%) | called by muse, mutect2, varscan2
- DOCK6 | c.2271G>C p.L757= | Silent (SNP) | VAF 51/325 reads (16%) | called by muse, mutect2, varscan2
- EML5 | c.5532T>C p.Y1844= (on ENST00000380664; = p.Y1852= on NM_183387.3) | Silent (SNP) | VAF 171/238 reads (72%) | catalogued as rs1233531682; called by muse, mutect2, varscan2
- FOXC2 | c.852C>T p.G284= | Silent (SNP) | VAF 7/111 reads (6%) | called by muse, mutect2
- FUCA1 | c.1173G>A p.K391= | Silent (SNP) | VAF 22/343 reads (6%) | catalogued as COSV100992132; called by muse, mutect2
- GREB1 | c.2056C>T p.L686= | Silent (SNP) | VAF 236/740 reads (32%) | called by muse, mutect2, varscan2
- IGHV3-66 | c.288G>A p.T96= | Silent (SNP) | VAF 25/205 reads (12%) | catalogued as rs781936076; called by muse, mutect2, varscan2
- IGKV6D-21 | c.243C>T p.F81= | Silent (SNP) | VAF 10/282 reads (4%) | called by muse, mutect2
- IGLL1 | c.135G>T p.S45= | Silent (SNP) | VAF 98/352 reads (28%) | called by mutect2, varscan2
- IRX1 | c.624C>T p.S208= | Silent (SNP) | VAF 48/784 reads (6%) | catalogued as COSV100116237, COSV57361038; called by muse, mutect2
- KEL | c.420C>T p.H140= | Silent (SNP) | VAF 82/412 reads (20%) | called by muse, mutect2, varscan2
- LCT | c.1044C>T p.H348= | Silent (SNP) | VAF 40/226 reads (18%) | catalogued as rs747424045, COSV99930724; called by muse, mutect2, varscan2
- LRRC66 | c.2301G>A p.K767= | Silent (SNP) | VAF 50/293 reads (17%) | called by muse, mutect2, varscan2
- PCDHA2 | c.1296G>A p.S432= | Silent (SNP) | VAF 84/447 reads (19%) | catalogued as rs1554119795, COSV65366882; called by muse, mutect2, varscan2
- PCM1 | c.297A>G p.E99= | Silent (SNP) | VAF 100/408 reads (25%) | called by muse, mutect2, varscan2
- PTGER4 | c.444G>T p.V148= | Silent (SNP) | VAF 736/958 reads (77%) | called by muse, mutect2, varscan2
- S1PR1 | c.759G>A p.A253= | Silent (SNP) | VAF 40/343 reads (12%) | catalogued as COSV59513350; called by muse, mutect2, varscan2
- SLC39A12 | c.1695A>G p.S565= (on ENST00000377369 / NM_001145195.2; = p.S528= on NM_152725.3) | Silent (SNP) | VAF 37/289 reads (13%) | catalogued as rs778646270, COSV66202702; called by muse, mutect2, varscan2
- SNX30 | c.24C>A p.A8= | Silent (SNP) | VAF 56/139 reads (40%) | called by muse, mutect2, varscan2
- TRIM50 | c.669C>A p.A223= | Silent (SNP) | VAF 167/603 reads (28%) | called by muse, mutect2, varscan2
- TRPV5 | c.1146T>C p.D382= | Silent (SNP) | VAF 24/124 reads (19%) | called by muse, mutect2, varscan2
- UBR4 | c.10173G>A p.L3391= | Silent (SNP) | VAF 11/128 reads (9%) | catalogued as rs1267866249; called by muse, mutect2
- ZFHX4 | c.2790C>T p.L930= | Silent (SNP) | VAF 29/218 reads (13%) | catalogued as COSV51486236; called by muse, mutect2, varscan2
- ZSCAN2 | c.262C>T p.L88= | Silent (SNP) | VAF 34/246 reads (14%) | called by muse, mutect2, varscan2
- AC136604.1 | chr5:179652317 G>A | 3'Flank (SNP) | VAF 334/1250 reads (27%) | catalogued as rs199867011; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1046+2948C>T | Intron (SNP) | VAF 360/614 reads (59%) | catalogued as rs1025321164; called by muse, mutect2, varscan2
- DSP | c.*46A>G | 3'UTR (SNP) | VAF 17/142 reads (12%) | called by muse, mutect2, varscan2
- GORASP2 | c.349-23G>T | Intron (SNP) | VAF 18/144 reads (13%) | called by muse, mutect2, varscan2
- HSPA7 | n.464C>T | RNA (SNP) | VAF 267/401 reads (67%) | catalogued as rs1184883911; called by muse, mutect2, varscan2
- ITIH5 | c.2032+793T>C | Intron (SNP) | VAF 8/135 reads (6%) | called by muse, mutect2
- KLF6 | c.*1805T>C | 3'UTR (SNP) | VAF 31/65 reads (48%) | called by mutect2, varscan2
- KLF6 | c.*1802del | 3'UTR (DEL) | VAF 20/59 reads (34%) | called by mutect2, pindel, varscan2
- LINC02724 | n.808T>C | RNA (SNP) | VAF 48/269 reads (18%) | called by muse, mutect2, varscan2
- NAIPP4 | n.527G>C | RNA (SNP) | VAF 20/256 reads (8%) | called by muse, mutect2, varscan2
- OSBPL2 | chr20:62232964 C>A | 5'Flank (SNP) | VAF 25/285 reads (9%) | called by muse, mutect2
- SLC35C2 | c.-171C>T | 5'UTR (SNP) | VAF 186/610 reads (30%) | catalogued as rs907841722; called by muse, mutect2, varscan2
- TDRD6 | c.*31A>C | 3'UTR (SNP) | VAF 13/154 reads (8%) | called by muse, mutect2
- TP53TG3D | c.*131-15T>A | Intron (SNP) | VAF 201/852 reads (24%) | called by muse, mutect2, varscan2
- ZNF300P1 | n.1215C>T | RNA (SNP) | VAF 24/176 reads (14%) | catalogued as rs1030325131; called by muse, mutect2, varscan2
